CCDI case PBCBHD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0e7e5e4f-045f-465f-b3fe-9c7046d60782

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.8 years (4,690 days).

Biospecimens (3 samples)
- Sample 0DNJA3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNJAU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNJB9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
